Surgical pathology report (de-identified scan), TCGA case TCGA-G4-6303, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G4-6303-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

- A. PERITONEAL IMPLANT
- B. SMALL BOWEL IMPLANT
- C. SIGMOID COLON
- D. RECTAL DONUT
- E. COLON DONUT

DIAGNOSIS:

- A. PERITONEAL IMPLANT:
- POSITIVE FOR ADENOCARCINOMA.
- B. SMALL BOWEL IMPLANT:
- POSITIVE FOR ADENOCARCINOMA.
- C. SIGMOID COLON, RESECTION:
- CIRCUMFERENTIAL EXOPHYTIC ULCERATED MODERATELY DIFFERENTIATED INVASIVE ADENOCARCINOMA OF SIGMOID COLON WITH FULL MUSCLE WALL THICKNESS INVASION, EXTENSION TO SUBSEROUSAL FAT WITH METASTASIS TO ONE OUT OF TWENTY FIVE LYMPH NODES AND WITH PERICOLIC FAT TUMOR IMPLANTS.(1/25)
- SIZE OF TUMOR 5 X 3.5 X 1.6 CM.
- MARGINS OF RESECTION- NEGATIVE FOR TUMOR.
- D. RECTAL DONUT:
- RING SEGMENT OF COLONIC TISSUE-- NEGATIVE FOR TUMOR.
- E. COLON DONUT:
- RING SEGMENT OF COLONIC TISSUE, NEGATIVE FOR TUMOR.

COLORECTAL CANCER TEMPLATE

Specimen Type:	Sigmoidectomy
Tumor Site:	Sigmoid colon
Tumor Configuration:	Exophytic (polypoid), infiltrative, ulcerating
Tumor Size:	5.0 x 3.5 x 1.6 cm
Histologic Type:	adenocarcinoma
Histologic Grade:	G2: Moderately differentiated
Extent of Invasion:	Lamina propria, submucosa, muscularis propria
Margins:	Margins uninvolved by invasive carcinoma (proximal, distal, radial)
Venous/Lymphatic Invasion:	Present
Perineural Invasion:	Absent
Additional Pathologic Findings:	tubular adenoma
Extent of Resection:	R0: Complete resection with grossly and microscopically negative margins
Lymph Nodes:	Positive (1/25)
Implants:	Present
EGFR Expression:	na
Pathologic Stage:	pT3 N1 Mx

NOTE: Nodular focus of tumor implant seen in slide #C13 and #C16.
Small focus of tubular adenoma in association with carcinoma seen in slide labelled #C 31.

SPECIMEN(S):

- A. PERITONEAL IMPLANT B. SMALL BOWEL IMPLANT C. SIGMOID COLON D. RECTAL DONUT E. COLON DONUT

CLINICAL HISTORY:

with carcinoma sigmoid colon

[page 2 of 2]
INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA: Soft tissue, peritoneal implant, bx:

- Metastatic poorly differentiated adenocarcinoma by

GROSS DESCRIPTION:

A. PERITONEAL IMPLANT:

Received fresh is a 1x0.8x0.7 cm. tan-red piece of tissue with tan-white solid cut surface. Half is submitted for frozen section and the other half is submitted in cassette A2.

B. SMALL BOWEL IMPLANT:

Received fresh is one fragment of tan-pink soft tissue measuring 1x0.5x0.4 cm. The specimen is submitted in toto in one cassette.

C. SIGMOID COLON: RESECTION

Received in fresh state is a resected segment of sigmoid colon with attached indurated pericolic fat measuring 17 cm in length. There is a firm, palpable mass with overlying indurated mesocolic fat in the mid segment of the specimen, which when opened shows an ulcerated exophytic circumferential tumor situated 10.5 cm and 9.0 cm from margins of resection. The tumor measures 5 x 3.5 x 1.6 cm. Cut section shows a tan dirty white granular firm surface infiltrating the full thickness of the colonic wall with extension into the subjacent adipose tissue. The remainder of the colonic mucosa shows prominent mucosal fold with hyperemia. Approximately 25 lymph nodes are identified ranging in size from 0.1 to 0.8 cm in diameter. Multiple sections are submitted as follows:

C1-C5: en bloc section of tumor with pericolic fat

C6-C7: sections from the resected margins

C8-10: sections from tumor area the colonic wall and area of tumor

C11-C24: sections from lymph nodes

C25-C31: additional more sections tumor and adjacent areas.

D. RECTAL DONUT:

Received in formalin is a piece of donut tissue measuring 2.5x1.8x0.8 cm. Specimen is bisected and submitted in toto in cassette D1 and D2.

E. COLON DONUT:

Received in formalin is a donut shaped tissue measuring 2.0x1.7x0.6 cm. The specimen is bisected and submitted in toto in cassette E1 and E2.

Also included is a n umbrella shaped like metallic object ,(rod measures 3.0cm.in length and head measures 3.0 cm in diameter.. Gross exam only.

Source: NCI Genomic Data Commons file 29aced4c-d606-4d1b-9ba2-2f42ed62b6f1 (TCGA-G4-6303.7427B7A6-357F-4F90-A25F-BF04DE709E5D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).